CTSP case CTSP-AD1A — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ea52221-8c19-41a6-88b1-7c38d9ebde18

Demographics
Sex at birth: female; Race: white; Year of birth: 1933; Vital status: Dead; Days to death: 79 days; Year of death: 2010; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 76.6 years (27,984 days); Method of diagnosis: Biopsy; Days to last follow up: 79 days; Best overall response: No Response; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55 kg; Height: 155 cm; BMI: 22.9.

Biospecimens (1 sample)
- Sample DLBCL11315-sample: Sample type: Tumor; Tissue type: Tumor.
